Gene-level copy-number profile of specimen HCM-CSHL-0186-C25-85A from HCMI case HCM-CSHL-0186-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,102 days).
Specimen HCM-CSHL-0186-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22bf7b76-8cab-4d22-87ba-18bea1edbc48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0186-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/1843265b-5583-4619-8878-d8f45e424b6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 10,151; copy number 2: 44,738; copy number 3: 3,934; copy number 4: 37; copy number 5: 1; copy number 6: 39; copy number 8: 8; copy number 10: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 54 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 6 (within-gene range 3–6): PRAMEF6, PRAMEF28P.
- chr6:28,378,955–29,142,934, 37 genes, copy number 6: ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, GPX6, GPX5, ZBED9, AL049543.1, AL121932.1, AL121932.2, LINC00533, RPSAP2, NOP56P1, AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14, TRIM27, RNU6-930P, LINC01556, KRT18P1, RN7SL471P, HCG15, AL662791.1, ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1.
- chr10:35,604,485–36,626,138, 15 genes, copy number 5–10: AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 7,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
